Somatic mutation profile of tumor specimen TCGA-CX-7085-01A (aliquot TCGA-CX-7085-01A-21D-2012-08) from TCGA case TCGA-CX-7085, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,221 days).
Specimen TCGA-CX-7085-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d56c3c24-3602-41f8-92d3-9df9eefbb056.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CX-7085-10A (Blood Derived Normal), aliquot TCGA-CX-7085-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77723fdf-356c-4668-8d36-fc96bf544e4a

The open-access MAF lists 98 somatic variants for this specimen: 76 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 21, Nonsense Mutation 7, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53027071; called by muse, mutect2, varscan2
- RAC1 | c.116A>G p.N39S | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); catalogued as rs1554263624, COSV61825223; ClinVar: pathogenic; called by muse, mutect2
- ACAD9 | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100459316; called by muse, varscan2
- ADAMTS17 | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV99171291; called by muse, mutect2
- ARMC4 | c.1759T>A p.C587S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100537148; called by muse, mutect2
- CACNB2 | c.1448C>G p.S483* (on ENST00000324631 / NM_201596.3; = p.S428* on NM_000724.4) | Nonsense Mutation (SNP) | VAF 12/336 reads (4%) | catalogued as COSV99995517; called by muse, mutect2
- CASP8 | c.1393C>T p.Q465* (on ENST00000432109 / NM_033355.3; = p.Q482* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV51844901; called by muse, mutect2, varscan2
- CDH5 | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV100439344, COSV58520266; called by muse, mutect2
- CMYA5 | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs762370988, COSV101484212; called by muse, mutect2
- CTNND1 | c.2614C>T p.L872F (on ENST00000399050 / NM_001085458.2; = p.L866F on NM_001331.3) | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62382227; called by muse, mutect2
- DDX42 | c.1419G>C p.Q473H | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834988; called by muse, mutect2
- DMTF1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100487457; called by muse, mutect2, varscan2
- ESR2 | c.1162C>T p.R388* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as rs772629994, COSV99963586; called by muse, mutect2, varscan2
- FAM135B | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99425834; called by muse, mutect2
- FAM83G | c.1790C>G p.S597* | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100525336; called by muse, mutect2, varscan2
- FAT1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499477, COSV71671689; called by muse, mutect2, varscan2
- FAT4 | c.1962C>G p.F654L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.302); catalogued as COSV101272531, COSV67895071; called by muse, mutect2, varscan2
- FCAR | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 34/482 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs780512814, COSV100628987; called by muse, mutect2
- FGFR3 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs766911583, COSV99602817; called by mutect2, varscan2
- FLRT2 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100420733; called by muse, mutect2
- GLI3 | c.815A>T p.H272L | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV101229956; called by muse, mutect2
- GRIA3 | c.1578G>C p.M526I | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV99991010; called by muse, mutect2
- GRK5 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100963161; called by muse, mutect2, varscan2
- INTS10 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs200349817, COSV101208717; called by muse, mutect2, varscan2
- IP6K3 | c.708G>C p.M236I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99539998; called by muse, mutect2, varscan2
- JADE3 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV99510075; called by muse, mutect2, varscan2
- KCNH6 | c.2425C>G p.Q809E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100121160; called by muse, mutect2, varscan2
- KDM3A | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100460721; called by muse, mutect2
- LAMA2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370655, COSV70352537; called by muse, mutect2
- LRIG2 | c.2431A>G p.I811V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1322756156, COSV100743544; called by muse, mutect2, varscan2
- LRRC37B | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100496395; called by muse, mutect2, varscan2
- LTBP4 | c.3136G>A p.G1046R (on ENST00000308370 / NM_001042544.1; = p.G1009R on NM_003573.2) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as rs562454425, COSV52581344; called by muse, mutect2, varscan2
- MAGEC1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV53568020, COSV53576550; called by muse, mutect2
- MKRN1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as COSV55436754; called by muse, mutect2
- MYADM | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100425137; called by muse, mutect2
- NAB1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100493092; called by muse, mutect2, varscan2
- NCKAP1L | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV99515416; called by muse, mutect2
- NPEPPS | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100443862, COSV59102201; called by muse, mutect2, varscan2
- NRP1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV104375226, COSV99589276; called by muse, mutect2
- NTMT1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.806); catalogued as COSV99475793; called by muse, mutect2
- OR2T6 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs201925418, COSV63216883; called by muse, mutect2, varscan2
- OR5AR1 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100265724; called by muse, mutect2
- OSCP1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.346); catalogued as COSV99347467; called by muse, mutect2
- PCDHA9 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV65328261; called by muse, mutect2, varscan2
- PCDHAC1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs1554203838, COSV53865444, COSV99167649; called by muse, mutect2, varscan2
- PCDHGA4 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99542626; called by muse, mutect2, varscan2
- PDCD11 | c.5187C>G p.I1729M | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV99588731; called by muse, mutect2
- PRICKLE2 | c.548G>A p.G183E (on ENST00000295902; = p.G127E on NM_198859.4) | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs774630443, COSV99897765; called by muse, mutect2
- RESF1 | c.1732C>G p.Q578E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1489417086, COSV100440472; called by muse, mutect2
- RSF1 | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100407541, COSV57840048; called by muse, mutect2
- SIN3A | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.239); catalogued as COSV100845195; called by muse, mutect2
- SLC45A2 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | catalogued as COSV99672341; called by muse, mutect2
- SLC7A11 | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99763326; called by muse, mutect2, varscan2
- SLCO6A1 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.355); catalogued as rs868354800, COSV65816352; called by muse, varscan2
- SMAP1 | c.724G>A p.D242N (on ENST00000370455 / NM_001044305.3; = p.D215N on NM_021940.5) | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100017220; called by muse, mutect2
- SMG1 | c.10156C>G p.Q3386E | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV101246550, COSV67173759; called by muse, mutect2
- SPHK2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs1203846768, COSV99709473; called by muse, mutect2, varscan2
- SPIN3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as COSV100888485; called by muse, mutect2, varscan2
- SRRT | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs751168051, COSV99574320; called by muse, mutect2, varscan2
- TAF1L | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99645075; called by muse, mutect2
- TENM3 | c.5924G>C p.G1975A | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101305285; called by muse, mutect2
- TGFBR1 | c.1323G>C p.M441I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV66627357; called by muse, mutect2, varscan2
- THOC2 | c.4409G>A p.R1470K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99833789; called by muse, mutect2
- TMEM131L | c.3907G>A p.D1303N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs373363345; called by muse, mutect2, varscan2
- TNFAIP1 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99134837; called by muse, mutect2
- TNFSF8 | c.118T>C p.Y40H | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV99802010; called by muse, mutect2
- TTBK2 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142119; called by muse, mutect2
- UGT2B11 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71423489; called by muse, mutect2
- WDR12 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.332); catalogued as COSV99651184; called by muse, mutect2
- YES1 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV58849381; called by muse, mutect2, varscan2
- ZNF274 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100465301; called by muse, mutect2, varscan2
- ZNF407 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1179958339, COSV55253739; called by muse, mutect2
- ZNF836 | c.2120C>G p.S707* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100441092; called by muse, mutect2, varscan2
- ACACA | c.2590C>G p.Q864E | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- FAT1 | c.10783_10789del p.T3595Afs*3 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2
- ACADS | c.150G>A p.E50= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV99656772; called by muse, mutect2
- ASCL1 | c.525C>T p.D175= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99902100; called by mutect2, varscan2
- CHMP2A | c.402G>A p.E134= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as COSV99448261; called by muse, mutect2
- CLPTM1 | c.813G>A p.V271= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV100493875; called by muse, mutect2
- COL6A3 | c.3195C>T p.V1065= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs1170658959, COSV99799951; called by muse, mutect2
- DAAM2 | c.1272G>A p.E424= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV99226389; called by muse, mutect2, varscan2
- GCN1 | c.7056C>T p.F2352= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100325676; called by muse, mutect2, varscan2
- IQCC | c.852G>A p.P284= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs752696604, COSV52212139; called by muse, mutect2, varscan2
- KIRREL2 | c.1839G>A p.L613= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV52880011; called by muse, mutect2, varscan2
- MEIOB | c.993C>G p.L331= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100379880; called by muse, mutect2
- MYLK | c.1035C>T p.I345= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV100659351; called by muse, mutect2
- OR4M1 | c.378C>T p.I126= | Silent (SNP) | VAF 20/572 reads (3%) | catalogued as COSV100271354; called by muse, mutect2
- OR51G2 | c.624C>T p.I208= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs371119617; called by mutect2, varscan2
- PPP1R10 | c.1350G>A p.L450= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as COSV100919912; called by muse, mutect2
- RUFY2 | c.498C>T p.L166= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100700140; called by muse, mutect2, varscan2
- SH2D2A | c.975C>T p.S325= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as rs966234572, COSV100949152; called by muse, mutect2
- SMARCAL1 | c.141C>T p.F47= | Silent (SNP) | VAF 15/227 reads (7%) | catalogued as rs749326502, COSV100619979; called by muse, mutect2
- TRHDE | c.564G>A p.A188= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99671705; called by muse, mutect2, varscan2
- TTF2 | c.3486C>T p.I1162= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as COSV101037673; called by muse, mutect2
- USO1 | c.942G>A p.Q314= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV99362989; called by muse, mutect2
- XKRX | c.447G>C p.L149= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV100139750; called by muse, mutect2
- SLC41A3 | c.274-5386C>G | Intron (SNP) | VAF 3/40 reads (8%) | catalogued as rs1012264985, COSV100259764; called by muse, mutect2
